Somatic mutation profile of tumor specimen TCGA-62-A46O-01A (aliquot TCGA-62-A46O-01A-11D-A24D-08) from TCGA case TCGA-62-A46O, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.8 years (24,050 days).
Specimen TCGA-62-A46O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0fbcc5a-9946-497e-85e1-0bcce29e2bb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-A46O-10A (Blood Derived Normal), aliquot TCGA-62-A46O-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a8c1df6-1e97-42ba-9cf6-429307324d55

The open-access MAF lists 971 somatic variants for this specimen: 747 protein-altering or splice-affecting, 206 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 629, Silent 206, Nonsense Mutation 55, Frame Shift Del 27, Splice Site 17, Splice Region 9, RNA 8, Intron 6, Frame Shift Ins 3, Translation Start Site 3, In Frame Del 3, 3'UTR 2.

Variants (750 of 971; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 34/51 reads (67%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- AASS | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.42); catalogued as rs1472570605, COSV100741601; called by muse, mutect2
- ABCA6 | c.4025G>T p.G1342V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52637925, COSV99445403; called by muse, mutect2, varscan2
- ABCB1 | c.467T>A p.M156K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99711759; called by muse, mutect2, varscan2
- ABCB11 | c.3836C>T p.T1279I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99791261; called by muse, mutect2, varscan2
- ABCB4 | c.2288T>A p.I763N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99709433; called by muse, mutect2, varscan2
- ABCB5 | c.2108G>T p.G703V (on ENST00000404938 / NM_001163941.2; = p.G258V on NM_178559.6) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51707521, COSV99327058; called by muse, mutect2, varscan2
- ACAD11 | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99391382; called by muse, mutect2, varscan2
- ACIN1 | c.3981C>G p.S1327R | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV99398840; called by muse, mutect2, varscan2
- ACSM5 | c.1564C>A p.P522T | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV100088213; called by muse, mutect2, varscan2
- ACTN4 | c.1062G>C p.E354D | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV99399634; called by muse, mutect2, varscan2
- ACVRL1 | c.338C>G p.P113R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.494); catalogued as COSV101187750; called by muse, mutect2, varscan2
- ADAD1 | c.634A>T p.I212F | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99634877; called by muse, mutect2, varscan2
- ADAMTS12 | c.412del p.L138Sfs*26 | Frame Shift Del (DEL) | VAF 25/60 reads (42%) | catalogued as COSV100711524, COSV61261596; called by mutect2, pindel, varscan2
- ADAMTS13 | c.4046G>T p.G1349V | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV99390041; called by muse, mutect2, varscan2
- ADAMTS17 | c.2651G>T p.R884L | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51489649, COSV99170293; called by muse, mutect2, varscan2
- ADGRB3 | c.3695C>A p.P1232H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.169); catalogued as COSV53233093, COSV53259433; called by muse, mutect2, varscan2
- ADNP2 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV100080448; called by muse, mutect2, varscan2
- ADRA2B | c.634G>T p.G212W | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs1395966598, COSV101337330; called by muse, mutect2, varscan2
- AGMO | c.657C>A p.S219R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs200156433, COSV100693338; called by muse, mutect2, varscan2
- AGPS | c.1695C>T p.C565= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99930888; called by muse, mutect2, varscan2
- AGRN | c.2217G>C p.Q739H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV101038483; called by muse, mutect2, varscan2
- AHCYL1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as COSV100779289; called by muse, mutect2, varscan2
- AKAP1 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs918385729, COSV100027652; called by muse, mutect2, varscan2
- AL135905.2 | c.*548-1G>T | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV101037686; called by muse, mutect2, varscan2
- ALPL | c.424A>T p.T142S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as COSV100876754; called by muse, mutect2, varscan2
- ALS2CL | c.2814G>C p.M938I | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as COSV100014591; called by muse, mutect2, varscan2
- AMER1 | c.1087G>T p.V363L | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100365058; called by muse, mutect2, varscan2
- AMER3 | c.1303G>T p.G435C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100365847; called by muse, mutect2, varscan2
- ANAPC5 | c.1357G>T p.A453S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99945858; called by muse, mutect2, varscan2
- ANO3 | c.335A>T p.Y112F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99879650; called by muse, mutect2, varscan2
- APBB1 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100193365; called by muse, mutect2, varscan2
- APOB | c.12097G>T p.D4033Y | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99262746, COSV99265587; called by muse, mutect2, varscan2
- ARAP3 | c.3972+1G>A p.X1324_splice | Splice Site (SNP) | VAF 31/88 reads (35%) | catalogued as COSV99499174; called by muse, mutect2, varscan2
- ARHGAP24 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101232896; called by muse, mutect2, varscan2
- ARHGEF17 | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99734676; called by muse, mutect2, varscan2
- ARID1B | c.2435A>T p.H812L | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.654); catalogued as COSV99266423; called by muse, mutect2, varscan2
- ARID1B | c.3048A>T p.K1016N | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99266427; called by muse, mutect2, varscan2
- ARMC1 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99394730; called by muse, mutect2, varscan2
- ARMC5 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.621); catalogued as rs766609669, COSV99192296; called by muse, mutect2, varscan2
- ARNT2 | c.1438G>T p.V480L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100308321; called by muse, mutect2, varscan2
- ASH1L | c.1518C>G p.F506L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs1280179227, COSV100853033; called by muse, mutect2, varscan2
- ASIC4 | c.163G>C p.G55R | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.095); catalogued as COSV100761518; called by muse, mutect2, varscan2
- ASTL | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV100668227, COSV60903568; called by muse, mutect2
- ASTN1 | c.2863C>A p.P955T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV100705161; called by muse, mutect2, varscan2
- ASXL1 | c.2894G>C p.R965P | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100037232; called by muse, mutect2, varscan2
- ATAD1 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100057886, COSV57758990; called by muse, mutect2, varscan2
- ATG16L1 | c.716A>T p.D239V | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100731202; called by muse, mutect2, varscan2
- ATP10B | c.4123C>T p.Q1375* | Nonsense Mutation (SNP) | VAF 45/155 reads (29%) | catalogued as COSV100513828; called by muse, mutect2
- ATRX | c.2030C>G p.S677* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as COSV100969776, COSV64876383; called by muse, mutect2, varscan2
- ATXN1 | c.10A>T p.N4Y | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99784442; called by muse, mutect2, varscan2
- BCKDHB | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57511752; called by muse, mutect2, varscan2
- BEST2 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99244136; called by muse, mutect2, varscan2
- BMX | c.1900C>A p.P634T | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564240; called by muse, mutect2, varscan2
- BOC | c.2168C>A p.A723E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99847773, COSV99848077; called by muse, mutect2, varscan2
- BRCA2 | c.9043A>T p.K3015* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101203794; called by muse, mutect2, varscan2
- BSN | c.10439del p.G3480Afs*7 | Frame Shift Del (DEL) | VAF 18/33 reads (55%) | catalogued as COSV56518895, COSV99608725; called by mutect2, pindel, varscan2
- BTAF1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.44); PolyPhen benign (0.406); catalogued as COSV99794677; called by muse, mutect2, varscan2
- C1orf87 | c.1592G>C p.G531A | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV100966859, COSV100967220, COSV64596320; called by muse, mutect2, varscan2
- C2orf49 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs760481415, COSV99307347; called by muse, mutect2, varscan2
- C9 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54676126, COSV54678955; called by muse, mutect2, varscan2
- CACNA1E | c.3996C>A p.N1332K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV100701114, COSV62390019; called by muse, mutect2, varscan2
- CACNG8 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99554787; called by muse, mutect2, varscan2
- CAD | c.3909G>A p.M1303I | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99254186; called by muse, mutect2, varscan2
- CAMK2B | c.1470C>G p.S490= | Splice Region (SNP) | VAF 34/61 reads (56%) | catalogued as COSV99322588; called by muse, mutect2, varscan2
- CARD11 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV101210380; called by muse, mutect2, varscan2
- CASC3 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.018); catalogued as COSV99229397; called by muse, mutect2, varscan2
- CAST | c.433G>T p.D145Y (on ENST00000341926; = p.D228Y on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100352068; called by muse, mutect2, varscan2
- CAVIN4 | c.968G>T p.R323M | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.518); catalogued as COSV100293048; called by muse, mutect2, varscan2
- CBLN4 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99290275; called by muse, mutect2, varscan2
- CBWD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1182680823, COSV99380056; called by muse, mutect2
- CCDC138 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99718628; called by muse, mutect2, varscan2
- CCDC66 | c.934A>T p.R312W (on ENST00000394672 / NM_001353147.1; = p.R278W on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100413542; called by muse, mutect2, varscan2
- CCDC70 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV99665277; called by muse, mutect2, varscan2
- CCDC88B | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100104825; called by muse, mutect2, varscan2
- CCNB3 | c.3981C>A p.Y1327* | Nonsense Mutation (SNP) | VAF 74/149 reads (50%) | catalogued as COSV99328271; called by muse, varscan2
- CCNDBP1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100281422; called by muse, mutect2, varscan2
- CCNJL | c.1281G>T p.M427I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99979089; called by muse, mutect2, varscan2
- CD163 | c.2244G>T p.W748C | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100775564; called by muse, mutect2, varscan2
- CD180 | c.1616C>G p.S539C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV56516673, COSV99842027; called by muse, mutect2, varscan2
- CD1B | c.927A>G p.I309M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV100939105; called by muse, mutect2, varscan2
- CD5L | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63821609; called by muse, mutect2, varscan2
- CD96 | c.1435G>T p.D479Y (on ENST00000283285 / NM_198196.3; = p.D463Y on NM_005816.5) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as COSV99342126; called by muse, mutect2, varscan2
- CDC42BPG | c.1395G>T p.R465S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV100711877; called by muse, varscan2
- CDCA2 | c.1076G>T p.S359I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV100398683; called by muse, mutect2, varscan2
- CDH11 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99216751; called by muse, mutect2, varscan2
- CDH4 | c.579C>A p.I193= | Splice Region (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100848168; called by muse, mutect2, varscan2
- CDK12 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV101420232; called by muse, mutect2, varscan2
- CENPI | c.1937C>T p.S646L | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54504360; called by muse, varscan2
- CFAP61 | c.1368C>A p.H456Q | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV99842469; called by muse, mutect2, varscan2
- CFDP1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV99382358; called by muse, mutect2, varscan2
- CFHR4 | c.1625G>T p.G542V (on ENST00000367416 / NM_001201551.2; = p.G296V on NM_006684.5) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52225148, COSV99259082; called by muse, mutect2, varscan2
- CIBAR2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 76/91 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs941917123, COSV101608257; called by muse, mutect2, varscan2
- CIP2A | c.2650A>C p.M884L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV99842535, COSV99842886; called by muse, mutect2, varscan2
- CLEC4G | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100183558; called by muse, mutect2, varscan2
- CLEC6A | c.553A>T p.T185S | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101165602; called by muse, mutect2, varscan2
- CLK4 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV100308758, COSV60321538; called by muse, mutect2, varscan2
- CLNK | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776088269, COSV99904351; called by mutect2, varscan2
- CLTCL1 | c.4027G>A p.V1343I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs782098593, COSV99594304; called by muse, mutect2, varscan2
- CMSS1 | c.790G>T p.G264* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101375432; called by muse, mutect2, varscan2
- CMYA5 | c.2534C>T p.S845F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs745604660, COSV101483688; called by muse, mutect2, varscan2
- CMYA5 | c.6703G>A p.D2235N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.113); catalogued as COSV101483690; called by muse, mutect2, varscan2
- CNTN2 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs772630695, COSV100084535; called by muse, mutect2, varscan2
- CNTNAP1 | c.3190C>T p.R1064W | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs143542325; called by muse, mutect2, varscan2
- CNTNAP2 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV100661442; called by muse, mutect2, varscan2
- COL11A1 | c.979G>T p.G327W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); catalogued as rs772411526, COSV100614303; called by muse, mutect2, varscan2
- COL12A1 | c.8362C>T p.Q2788* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100485088; called by muse, mutect2, varscan2
- COL14A1 | c.2627T>G p.F876C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99917504; called by muse, mutect2, varscan2
- COL1A2 | c.2333G>C p.G778A | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99798048; called by muse, mutect2, varscan2
- COL28A1 | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); catalogued as rs747716544, COSV101258227; called by muse, mutect2, varscan2
- COL5A2 | c.3572G>T p.G1191V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879871; called by muse, mutect2, varscan2
- COL5A3 | c.2363G>T p.G788V | Missense Mutation (SNP) | VAF 81/105 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99317972; called by muse, mutect2, varscan2
- COL5A3 | c.2362G>T p.G788W | Missense Mutation (SNP) | VAF 80/104 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317975; called by muse, mutect2, varscan2
- COL6A6 | c.634G>T p.G212* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100649632; called by muse, mutect2, varscan2
- COL9A3 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV100673206; called by muse, mutect2
- COL9A3 | c.548C>A p.P183Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV100673207; called by muse, mutect2
- CPSF1 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100574080; called by muse, mutect2, varscan2
- CPSF1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs782120667, COSV100574083; called by muse, mutect2, varscan2
- CPZ | c.1127C>T p.S376L (on ENST00000360986 / NM_001014447.3; = p.S365L on NM_003652.3) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100248651; called by muse, mutect2, varscan2
- CSDE1 | c.2321G>C p.R774P (on ENST00000358528 / NM_001007553.3; = p.R743P on NM_007158.6) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99793757; called by muse, mutect2
- CSMD1 | c.440A>T p.N147I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV101211935; called by muse, mutect2, varscan2
- CSMD2 | c.3846G>C p.Q1282H | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV99584056; called by muse, mutect2, varscan2
- CSMD3 | c.9521G>C p.G3174A (on ENST00000297405 / NM_001363185.1; = p.G3005A on NM_052900.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99820182; called by muse, mutect2, varscan2
- CSNK1A1L | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101131051; called by muse, mutect2, varscan2
- CSNK2A2 | c.305T>A p.V102E | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99345102; called by muse, mutect2
- CSPG4 | c.3289G>T p.G1097W | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413177; called by muse, mutect2
- CTNNA2 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.065); catalogued as COSV100781182, COSV63570327; called by muse, mutect2, varscan2
- CTNND2 | c.3187C>T p.R1063C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1561136061, COSV58892661; called by muse, mutect2, varscan2
- CUL4B | c.2335A>T p.R779W | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100340041; called by muse, mutect2, varscan2
- CYP2C9 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 67/85 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99582030; called by muse, mutect2, varscan2
- CYP4A11 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs372832923; called by muse, mutect2, varscan2
- CYSLTR2 | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as COSV99935070, COSV99935404; called by muse, mutect2, varscan2
- DAGLA | c.2257G>C p.D753H | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.667); catalogued as COSV99943833; called by muse, mutect2, varscan2
- DAOA | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV100298588; called by muse, mutect2, varscan2
- DCAF8 | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs61741888, COSV100470020; called by muse, mutect2, varscan2
- DCHS1 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV100201288; called by muse, mutect2
- DCSTAMP | c.449G>A p.W150* | Nonsense Mutation (SNP) | VAF 40/79 reads (51%) | catalogued as COSV52579302, COSV99885930; called by muse, mutect2, varscan2
- DDC | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100779062; called by muse, mutect2, varscan2
- DENND5A | c.3637G>C p.G1213R | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100063771; called by muse, mutect2, varscan2
- DGUOK | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137902450; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIPK2A | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100237017, COSV59856498; called by muse, mutect2
- DLC1 | c.29G>T p.W10L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs1312246284, COSV99360220; called by muse, mutect2, varscan2
- DLG4 | c.917A>T p.D306V (on ENST00000399506 / NM_001321075.3; = p.D349V on NM_001365.4) | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100263315; called by muse, mutect2, varscan2
- DLGAP2 | c.1539G>T p.Q513H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV101420952; called by muse, mutect2
- DMD | c.4368G>T p.M1456I | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100817152, COSV100824058; called by muse, mutect2, varscan2
- DNAH3 | c.4064C>T p.S1355F | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV54527180; called by muse, mutect2, varscan2
- DNAH7 | c.11410G>T p.V3804L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as COSV56790553; called by muse, mutect2, varscan2
- DNAH8 | c.11221A>G p.T3741A | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100542583; called by muse, mutect2, varscan2
- DNAH9 | c.8207T>A p.L2736H | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as COSV99302970; called by muse, mutect2, varscan2
- DNAJB2 | c.533G>C p.R178P | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV100338775, COSV60675863, COSV60678094; called by muse, mutect2, varscan2
- DSCAM | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101258614; called by muse, mutect2, varscan2
- DSG4 | c.2853T>A p.C951* | Nonsense Mutation (SNP) | VAF 46/60 reads (77%) | catalogued as COSV100355061; called by muse, mutect2, varscan2
- DSP | c.3115G>C p.E1039Q | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV101131146; called by muse, mutect2, varscan2
- DST | c.10568A>G p.K3523R | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV99749282; called by muse, mutect2, varscan2
- DUSP10 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100099960; called by muse, mutect2, varscan2
- DZIP3 | c.3105G>T p.E1035D | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV100847537; called by muse, mutect2, varscan2
- EDARADD | c.262C>A p.P88T (on ENST00000334232 / NM_145861.4; = p.P78T on NM_080738.4) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100512453; called by muse, mutect2, varscan2
- EEF1AKNMT | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV100675711; called by muse, mutect2, varscan2
- EEF2 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV100500511; called by muse, mutect2, varscan2
- EIF3L | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101094369; called by muse, mutect2, varscan2
- ELANE | c.13C>A p.R5S | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as COSV52255108; called by muse, mutect2, varscan2
- ELFN2 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101297442; called by muse, varscan2
- ENPP2 | c.2410G>T p.E804* (on ENST00000075322 / NM_001040092.3; = p.E856* on NM_006209.5) | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99307153; called by muse, mutect2, varscan2
- EPB41L3 | c.1828A>T p.N610Y | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV59457265; called by muse, mutect2, varscan2
- EPHA3 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100341609, COSV60708592, COSV60729757; called by muse, mutect2, varscan2
- EPHA7 | c.487A>G p.R163G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100992341; called by muse, mutect2, varscan2
- EPPK1 | c.4755G>C p.M1585I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV101599701, COSV73261073; called by muse, varscan2
- EPS8L3 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV100719639; called by muse, mutect2, varscan2
- ERC1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.266); catalogued as COSV100705538; called by muse, mutect2, varscan2
- EVA1C | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs768813253, COSV100291023; called by muse, mutect2, varscan2
- EXO1 | c.1514+1G>T p.X505_splice | Splice Site (SNP) | VAF 32/86 reads (37%) | catalogued as COSV100799555; called by muse, varscan2
- EXOC3L2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV52972841; called by muse, mutect2, varscan2
- F2RL1 | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); catalogued as COSV99688605; called by muse, mutect2, varscan2
- FADS2 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 48/109 reads (44%) | catalogued as COSV99608299; called by muse, mutect2, varscan2
- FAM155A | c.62C>G p.A21G | Missense Mutation (SNP) | VAF 140/237 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV101026135; called by muse, mutect2, varscan2
- FAM168B | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.266); catalogued as COSV101112201; called by muse, mutect2, varscan2
- FAM47A | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.71); PolyPhen benign (0.088); catalogued as COSV100649643; called by muse, mutect2, varscan2
- FAM47C | c.2147C>A p.A716E | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT tolerated (0.13); PolyPhen benign (0.413); catalogued as COSV100792214, COSV63723394; called by muse, mutect2, varscan2
- FAM71B | c.1295G>T p.R432I | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100261651; called by muse, mutect2, varscan2
- FAM83A | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 81/170 reads (48%) | catalogued as COSV99413897; called by muse, mutect2, varscan2
- FANCM | c.2161-1G>C p.X721_splice | Splice Site (SNP) | VAF 22/26 reads (85%) | catalogued as COSV57507492, COSV99950213; called by muse, mutect2, varscan2
- FASLG | c.206C>G p.P69R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100390293, COSV100390302; called by muse, mutect2, varscan2
- FAT1 | c.4220G>T p.G1407V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV101498581; called by muse, mutect2
- FAT4 | c.11389G>A p.G3797R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1218915760, COSV100626803, COSV58673045, COSV58704036; called by muse, mutect2, varscan2
- FBXO24 | c.1598A>T p.Q533L (on ENST00000241071 / NM_033506.3; = p.Q571L on NM_012172.5) | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99574822; called by muse, mutect2, varscan2
- FDX2 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100593656; called by muse, mutect2, varscan2
- FGF18 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99208499; called by muse, mutect2, varscan2
- FGF5 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs376426021; called by muse, mutect2, varscan2
- FGFBP1 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV99468855; called by muse, mutect2, varscan2
- FLACC1 | c.368G>T p.R123M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99629567; called by muse, mutect2, varscan2
- FLAD1 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99421805; called by muse, mutect2, varscan2
- FLCN | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as CD083305, COSV99549975; called by muse, mutect2, varscan2
- FLG2 | c.2407C>T p.Q803* | Nonsense Mutation (SNP) | VAF 182/911 reads (20%) | catalogued as COSV101165526; called by muse, mutect2, varscan2
- FLNA | c.988-1G>T p.X330_splice | Splice Site (SNP) | VAF 50/71 reads (70%) | catalogued as COSV100774191; called by muse, mutect2, varscan2
- FLRT2 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 61/87 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100419847; called by muse, mutect2, varscan2
- FSIP2 | c.20678C>A p.T6893N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1020869069, COSV100553450; called by mutect2, varscan2
- FZD1 | c.278_279insGCT p.P93_Q94insL | In Frame Ins (INS) | VAF 24/45 reads (53%) | catalogued as COSV55308743, COSV99842303; called by mutect2, varscan2
- GABRA1 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV50099661; called by muse, mutect2, varscan2
- GABRA6 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99193995; called by muse, mutect2, varscan2
- GAD2 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99392240; called by muse, mutect2, varscan2
- GAGE10 | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 114/244 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV101339907; called by muse, mutect2, varscan2
- GALNT13 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101221753, COSV67229712; called by muse, varscan2
- GALNT13 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101221754; called by muse, varscan2
- GALNT17 | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 25/31 reads (81%) | catalogued as COSV100351621, COSV61162908; called by muse, mutect2, varscan2
- GAN | c.503A>C p.E168A | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV101633948; called by muse, mutect2, varscan2
- GDAP2 | c.560-1G>C p.X187_splice | Splice Site (SNP) | VAF 25/51 reads (49%) | catalogued as COSV101031789; called by muse, mutect2, varscan2
- GDF5 | c.554G>C p.R185T | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV100976669; called by muse, mutect2, varscan2
- GEMIN5 | c.3034A>T p.K1012* | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | catalogued as COSV99593479; called by muse, mutect2, varscan2
- GGCX | c.514A>C p.T172P | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.356); catalogued as rs919781419, COSV99289547; called by muse, mutect2, varscan2
- GJA10 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV101005261, COSV65355724; called by muse, mutect2, varscan2
- GJC3 | c.741C>A p.S247R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs754890102, COSV100458329; called by muse, mutect2, varscan2
- GLI3 | c.3854C>A p.P1285H | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV67891973; called by muse, mutect2, varscan2
- GLP1R | c.1043G>T p.R348I | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100952411; called by muse, mutect2, varscan2
- GLS | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289627; called by muse, mutect2, varscan2
- GNAS | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV100004869, COSV58347289; called by muse, mutect2, varscan2
- GOLGB1 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100510139, COSV104415558; called by muse, mutect2, varscan2
- GPAA1 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100283933, COSV60155192, COSV60155245; called by muse, mutect2
- GPAA1 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV100283934; called by muse, mutect2, varscan2
- GPATCH8 | c.3235G>A p.D1079N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV100132368; called by muse, mutect2, varscan2
- GPC4 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 56/82 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100895326; called by muse, mutect2, varscan2
- GPR101 | c.849C>A p.S283R | Missense Mutation (SNP) | VAF 103/139 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as COSV99981196; called by muse, mutect2, varscan2
- GPR135 | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101229275; called by muse, mutect2, varscan2
- GPR148 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs74772195, COSV99998458; called by muse, mutect2, varscan2
- GPR149 | c.104A>C p.Y35S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101077987; called by muse, mutect2, varscan2
- GPR155 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV99789581; called by muse, mutect2, varscan2
- GPR158 | c.1901T>A p.L634H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100892570; called by muse, mutect2, varscan2
- GPR173 | c.825G>T p.M275I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as COSV100211951; called by muse, mutect2
- GREM2 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs1377063510, COSV100547888, COSV58956914; called by muse, mutect2, varscan2
- GTF2E1 | c.910G>C p.A304P | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs140000454, COSV52204033; called by muse, mutect2, varscan2
- GTSE1 | c.1986G>T p.Q662H | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.693); catalogued as COSV101483182; called by muse, mutect2, varscan2
- GTSF1L | c.177T>A p.H59Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100883887; called by muse, mutect2, varscan2
- GUCY1A2 | c.468G>T p.Q156H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV99972079, COSV99972106; called by muse, mutect2, varscan2
- HAS2 | c.167A>C p.H56P | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100391346, COSV100391654; called by muse, mutect2, varscan2
- HCN1 | c.2164C>A p.P722T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV100297694, COSV100301521, COSV57521384; called by muse, mutect2, varscan2
- HDAC6 | c.134C>G p.P45R | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100490441, COSV61928773; called by muse, mutect2, varscan2
- HDAC6 | c.1223C>A p.P408H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100490444; called by muse, mutect2, varscan2
- HEATR5B | c.3452G>T p.G1151V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99247875; called by muse, mutect2, varscan2
- HELZ2 | c.2501C>T p.S834F (on ENST00000467148 / NM_001037335.2; = p.S265F on NM_033405.3) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100915380, COSV100915734; called by muse, mutect2, varscan2
- HEPH | c.71C>A p.A24D (on ENST00000343002; = p.A78D on NM_138737.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.066); catalogued as COSV100293775; called by muse, mutect2, varscan2
- HEPH | c.3077C>G p.P1026R (on ENST00000343002; = p.P759R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100293780; called by muse, mutect2, varscan2
- HHIPL2 | c.1267C>A p.R423S | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100596484; called by muse, mutect2
- HNRNPAB | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV100359113; called by muse, mutect2, varscan2
- HOXA9 | c.344C>A p.T115K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV100604268, COSV58655853; called by muse, mutect2, varscan2
- HPS5 | c.2737C>G p.L913V (on ENST00000349215 / NM_181507.2; = p.L799V on NM_007216.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100752212; called by muse, mutect2, varscan2
- HUWE1 | c.6313G>A p.D2105N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV99469983; called by muse, mutect2, varscan2
- HYDIN | c.6403C>G p.L2135V | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV99991618; called by muse, mutect2, varscan2
- IDO2 | c.1055C>A p.T352N (on ENST00000389060; = p.T365N on NM_194294.2) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV100584432; called by muse, mutect2, varscan2
- IFNAR2 | c.682A>T p.T228S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV100577048; called by muse, mutect2, varscan2
- IFT172 | c.1049A>T p.K350M | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99561486; called by muse, mutect2, varscan2
- IGDCC4 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100732584; called by muse, mutect2, varscan2
- IGF2BP3 | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324804; called by muse, mutect2, varscan2
- IGFL1 | c.260T>A p.M87K | Missense Mutation (SNP) | VAF 264/340 reads (78%) | SIFT tolerated (0.34); PolyPhen benign (0.069); catalogued as COSV101473040; called by muse, mutect2, varscan2
- IGKV1-5 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs529842388; called by muse, mutect2, varscan2
- IGKV1D-33 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as COSV101134025; called by mutect2, varscan2
- IL13RA2 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99682792; called by muse, mutect2, varscan2
- IL36RN | c.304C>G p.R102G | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as CM132983, COSV100697211, COSV100697304; called by muse, mutect2, varscan2
- INPP1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100487051; called by muse, mutect2
- INPP1 | c.839G>T p.C280F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV59417684; called by muse, mutect2, varscan2
- INPP5D | c.2909T>A p.I970K (on ENST00000445964 / NM_001017915.3; = p.I969K on NM_005541.5) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV100856415; called by muse, mutect2, varscan2
- IQGAP3 | c.4610A>T p.Y1537F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1195100345, COSV100752009; called by muse, mutect2, varscan2
- IQSEC1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 44/61 reads (72%) | catalogued as COSV99831121; called by muse, mutect2, varscan2
- IRGC | c.1145A>T p.Y382F | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99745927; called by muse, mutect2, varscan2
- ISOC1 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV51491321, COSV99434289; called by muse, mutect2, varscan2
- ITGA2B | c.2879G>T p.W960L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.526); catalogued as COSV99288422; called by muse, mutect2, varscan2
- ITGAD | c.2283T>A p.S761= | Splice Region (SNP) | VAF 18/68 reads (26%) | catalogued as COSV101210220; called by muse, mutect2, varscan2
- ITPRIP | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99532344; called by muse, mutect2, varscan2
- ITSN1 | c.1827A>T p.E609D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as COSV101180427; called by muse, mutect2, varscan2
- JPH4 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV62509386; called by mutect2, varscan2
- KAT8 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99571018; called by muse, mutect2, varscan2
- KAZN | c.830A>T p.Q277L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100747578; called by muse, mutect2, varscan2
- KCNH7 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs946740260, COSV59815460; called by muse, mutect2, varscan2
- KCNK10 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100066913, COSV56639664; called by muse, mutect2, varscan2
- KCNQ4 | c.770A>C p.Y257S | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100714247; called by muse, mutect2
- KDR | c.2423C>A p.P808Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV99816361; called by muse, mutect2, varscan2
- KEAP1 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50457623, COSV50633810, COSV99407141; called by muse, mutect2, varscan2
- KIAA0513 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs773909160, COSV99260289; called by muse, mutect2, varscan2
- KIAA1549L | c.2966T>A p.I989N (on ENST00000321505; = p.I1286N on NM_012194.3) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99682444; called by muse, mutect2, varscan2
- KIAA1549L | c.2968G>C p.V990L (on ENST00000321505; = p.V1287L on NM_012194.3) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV55773761, COSV99682446; called by muse, mutect2, varscan2
- KIF2B | c.1515C>G p.D505E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99274420; called by muse, mutect2, varscan2
- KIF4A | c.3325G>T p.D1109Y | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV100979272; called by muse, mutect2, varscan2
- KIF5C | c.2482G>T p.A828S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV101276078; called by muse, mutect2, varscan2
- KIRREL1 | c.1499G>C p.G500A | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV100779141; called by muse, mutect2, varscan2
- KLHL7 | c.1530G>T p.M510I (on ENST00000339077 / NM_001031710.3; = p.M462I on NM_018846.5) | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100177565; called by muse, mutect2, varscan2
- KLK6 | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 18/26 reads (69%) | catalogued as COSV100037553; called by muse, mutect2, varscan2
- KMT2A | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); catalogued as COSV100627496; called by muse, mutect2, varscan2
- KNG1 | c.1868G>C p.S623T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99404928; called by muse, mutect2, varscan2
- KRT74 | c.1523del p.G508Efs*53 | Frame Shift Del (DEL) | VAF 47/166 reads (28%) | catalogued as rs758691730, COSV59772902; called by mutect2, pindel, varscan2
- KRTAP13-1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV100819825; called by muse, mutect2, varscan2
- KRTAP4-4 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs781355642, COSV101180520; called by muse, mutect2, varscan2
- KRTAP5-3 | c.227del p.G76Afs*190 | Frame Shift Del (DEL) | VAF 64/140 reads (46%) | catalogued as rs750587906; called by mutect2, pindel, varscan2
- KRTAP6-2 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 37/61 reads (61%) | PolyPhen benign (0.061); catalogued as COSV100588876; called by muse, mutect2, varscan2
- KY | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as rs368780624, COSV101414926; called by muse, mutect2, varscan2
- LAMA4 | c.4275T>A p.S1425R (on ENST00000230538 / NM_001105206.3; = p.S1418R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100037349; called by muse, mutect2, varscan2
- LAMA4 | c.3505C>T p.P1169S (on ENST00000230538 / NM_001105206.3; = p.P1162S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100037351; called by muse, mutect2, varscan2
- LARP4 | c.1667G>T p.S556I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV99528923; called by muse, mutect2, varscan2
- LARP4 | c.1667+1G>T p.X556_splice | Splice Site (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99528924; called by muse, mutect2, varscan2
- LCE4A | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 224/340 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100139965; called by muse, varscan2
- LCTL | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.322); catalogued as COSV100427118; called by muse, mutect2, varscan2
- LDLRAD4 | c.393C>A p.I131= | Splice Region (SNP) | VAF 51/59 reads (86%) | catalogued as COSV63335461; called by muse, mutect2, varscan2
- LGALS9B | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as COSV100162815; called by muse, mutect2, varscan2
- LINS1 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100129843; called by muse, mutect2, varscan2
- LLGL2 | c.1673G>T p.W558L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99388682; called by muse, mutect2
- LPAR3 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 107/193 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101004636; called by muse, mutect2, varscan2
- LRP1B | c.10128T>A p.C3376* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV101249478; called by muse, mutect2, varscan2
- LRP1B | c.684C>A p.S228R | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV101249480; called by muse, mutect2, varscan2
- LRRC4C | c.1688C>G p.T563R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as COSV99536474; called by muse, mutect2, varscan2
- LRRK1 | c.3833A>G p.K1278R | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1487742727, COSV99436869; called by muse, mutect2, varscan2
- LRRN4CL | c.410G>C p.R137T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs758513598, COSV99627753; called by muse, mutect2, varscan2
- LTK | c.2261G>T p.R754L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99540471; called by muse, mutect2, varscan2
- LY9 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 84/155 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1269333044, COSV99625948; called by muse, mutect2, varscan2
- LZTS1 | c.1405A>T p.N469Y | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV99742498; called by muse, mutect2, varscan2
- M1AP | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99283872; called by muse, mutect2, varscan2
- MACF1 | c.9619C>G p.L3207V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as rs779964288, COSV99240267; called by muse, mutect2, varscan2
- MACF1 | c.20569G>C p.E6857Q (on ENST00000372915; = p.E4902Q on NM_012090.5) | Missense Mutation (SNP) | VAF 68/162 reads (42%) | catalogued as COSV57106240, COSV99240271; called by muse, mutect2, varscan2
- MAGEB18 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57465316; called by muse, mutect2, varscan2
- MAGEC2 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.24); PolyPhen benign (0.154); catalogued as COSV99909301; called by muse, mutect2, varscan2
- MAGED2 | c.1414del p.A472Qfs*12 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | catalogued as COSV99514770; called by mutect2, pindel, varscan2
- MAGEE1 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.903); catalogued as COSV100819201; called by muse, mutect2, varscan2
- MAP2 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99557055; called by muse, mutect2, varscan2
- MAP2K4 | c.1064G>C p.R355T | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62254581; called by muse, mutect2, varscan2
- MAP3K3 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62280141; called by muse, mutect2
- MAP3K9 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101173401; called by muse, mutect2, varscan2
- MAP7 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.188); catalogued as COSV100643630; called by muse, mutect2, varscan2
- MARCHF11 | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100197185; called by muse, mutect2, varscan2
- MED12 | c.6044G>T p.R2015M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100375204, COSV61359255; called by muse, mutect2, varscan2
- MED12 | c.6044+1G>T p.X2015_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100375207; called by muse, mutect2, varscan2
- MED13L | c.5096G>T p.W1699L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99927502; called by muse, mutect2, varscan2
- MEFV | c.1108del p.Q370Sfs*10 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as COSV54826732; called by mutect2, pindel, varscan2
- MEGF8 | c.5981C>T p.A1994V (on ENST00000251268 / NM_001271938.2; = p.A1927V on NM_001410.3) | Missense Mutation (SNP) | VAF 91/418 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0.037); catalogued as rs1246408795, COSV99233909; called by muse, mutect2, varscan2
- MEMO1 | c.578G>C p.W193S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99703494; called by muse, mutect2, varscan2
- MFSD6 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV55622044, COSV99854934; called by muse, mutect2, varscan2
- MFSD6 | c.1426A>G p.N476D | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.828); catalogued as COSV99854935; called by muse, mutect2, varscan2
- MGST2 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as rs764475226, COSV99643495; called by muse, mutect2, varscan2
- MICAL2 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99816492; called by muse, mutect2, varscan2
- MISP | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99296518; called by muse, mutect2, varscan2
- MMP1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59510648; called by muse, mutect2, varscan2
- MMS22L | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV99245814; called by muse, mutect2, varscan2
- MOGS | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV99280764; called by muse, mutect2, varscan2
- MORF4L2 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 69/84 reads (82%) | catalogued as COSV100846337; called by muse, mutect2, varscan2
- MROH7 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV59871422; called by muse, mutect2
- MS4A2 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99626914; called by muse, mutect2, varscan2
- MSI2 | c.869G>T p.S290I | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99401339; called by muse, mutect2, varscan2
- MTFR2 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as COSV100886641; called by muse, mutect2, varscan2
- MUC16 | c.37109G>C p.G12370A | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV101197307; called by muse, mutect2, varscan2
- MUC16 | c.24634G>A p.E8212K | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as COSV67475048; called by muse, mutect2, varscan2
- MUC17 | c.4292C>A p.A1431D | Missense Mutation (SNP) | VAF 262/553 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV100071014; called by muse, mutect2, varscan2
- MUC6 | c.5132C>A p.T1711N | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as COSV70139709, COSV70149834; called by muse, mutect2
- MXD1 | c.619A>G p.K207E | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV100037383; called by muse, mutect2, varscan2
- MYH3 | c.703A>T p.K235* | Nonsense Mutation (SNP) | VAF 50/65 reads (77%) | catalogued as COSV99877502; called by muse, mutect2, varscan2
- MYH9 | c.845C>G p.S282C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99337550; called by muse, mutect2, varscan2
- MYO9A | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs536363522, COSV100612422; called by muse, mutect2, varscan2
- MYO9B | c.3872C>T p.P1291L | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1174978518, COSV101261052; called by muse, mutect2, varscan2
- MYOM3 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs563483726, COSV100292216; called by muse, mutect2, varscan2
- NAPEPLD | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV100439633; called by muse, mutect2, varscan2
- NAV3 | c.3553G>A p.G1185R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1316998679, COSV57060198, COSV57111020, COSV99885621; called by muse, mutect2, varscan2
- NBR1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100357630; called by muse, mutect2, varscan2
- NCCRP1 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 61/415 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.563); catalogued as rs565794896, COSV100355689; called by muse, mutect2, varscan2
- NCKAP5 | c.1654C>A p.P552T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.068); catalogued as COSV100489268; called by muse, mutect2, varscan2
- NCOR2 | c.2458C>G p.P820A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100656547, COSV62301834; called by muse, mutect2, varscan2
- NEB | c.11706C>G p.D3902E | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV99413349; called by muse, mutect2, varscan2
- NEB | c.5266G>T p.D1756Y | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99413352; called by muse, mutect2, varscan2
- NELL2 | c.1732T>A p.W578R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100418337; called by muse, mutect2, varscan2
- NELL2 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); catalogued as rs769425547, COSV100418344, COSV100420210, COSV61576556; called by muse, varscan2
- NEU2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 76/143 reads (53%) | catalogued as COSV99290388, COSV99290573; called by muse, mutect2, varscan2
- NFASC | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV100362357; called by muse, mutect2, varscan2
- NFASC | c.1474C>A p.R492S (on ENST00000339876 / NM_001378329.1; = p.R503S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100362363, COSV58358373; called by muse, mutect2, varscan2
- NLRP10 | c.1746C>A p.N582K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs368801555, COSV100149389; called by muse, varscan2
- NLRP10 | c.1738C>A p.Q580K | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV100149392, COSV100149826; called by muse, varscan2
- NLRP11 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 43/50 reads (86%) | catalogued as COSV100789598, COSV100789614; called by muse, mutect2, varscan2
- NPAP1 | c.3347T>C p.V1116A | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.012); catalogued as COSV100274536; called by muse, varscan2
- NPAS3 | c.187C>A p.R63S (on ENST00000356141 / NM_001164749.2; = p.R33S on NM_022123.3) | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100385342, COSV58094126; called by muse, mutect2, varscan2
- NPHP4 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100976640; called by muse, mutect2, varscan2
- NRG2 | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56832281, COSV99179848; called by muse, mutect2, varscan2
- NRXN1 | c.2815G>T p.D939Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100452509; called by muse, mutect2, varscan2
- NT5C1A | c.1028T>A p.V343E | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV99348194; called by muse, mutect2, varscan2
- NTRK3 | c.2462A>G p.Y821C (on ENST00000360948 / NM_001012338.2; = p.Y807C on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs766455393, COSV100711970, COSV62299781; called by muse, mutect2, varscan2
- NXPE3 | c.1571G>T p.W524L | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99839649; called by muse, mutect2, varscan2
- NXPE4 | c.1239G>T p.M413I (on ENST00000375478 / NM_001077639.2; = p.M129I on NM_017678.3) | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100970265; called by muse, mutect2, varscan2
- ONECUT2 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101529726; called by muse, mutect2, varscan2
- OPRM1 | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as COSV100000062; called by muse, mutect2, varscan2
- OR14A16 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as COSV100713646; called by muse, mutect2, varscan2
- OR14K1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV99314885; called by muse, mutect2, varscan2
- OR2G2 | c.413T>A p.L138* | Nonsense Mutation (SNP) | VAF 81/223 reads (36%) | catalogued as COSV100189493, COSV60739267; called by muse, mutect2, varscan2
- OR2L13 | c.491A>T p.H164L | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV100813632, COSV63554422; called by muse, mutect2, varscan2
- OR2T1 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.408); catalogued as COSV100822235; called by muse, mutect2, varscan2
- OR2T11 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100424666, COSV58184782; called by muse, mutect2, varscan2
- OR2T3 | c.885C>A p.Y295* | Nonsense Mutation (SNP) | VAF 32/218 reads (15%) | catalogued as COSV100612985; called by mutect2, varscan2
- OR2T33 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs764655627, COSV100532385, COSV58815735, COSV58817782; called by muse, varscan2
- OR2T8 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs758294510, COSV100177951, COSV100178597; called by mutect2, varscan2
- OR4A15 | c.310T>G p.L104V | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV100123730; called by muse, mutect2, varscan2
- OR4D5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs753810459, COSV100189622; called by muse, mutect2, varscan2
- OR51B4 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV100970198; called by muse, mutect2, varscan2
- OR51B5 | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100332365, COSV56175920; called by muse, mutect2, varscan2
- OR51D1 | c.401A>T p.D134V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100712329; called by muse, mutect2, varscan2
- OR52E2 | c.579C>A p.S193R | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100384539; called by muse, mutect2, varscan2
- OR52K2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 85/138 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs1183765115, COSV57836041; called by muse, mutect2, varscan2
- OR52L1 | c.828del p.F277Sfs*36 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs773768822; called by mutect2, pindel, varscan2
- OR52R1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100617550; called by muse, mutect2, varscan2
- OR5B2 | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV100222700; called by muse, mutect2, varscan2
- OR5T1 | c.541T>C p.C181R | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV100478615; called by muse, mutect2, varscan2
- OR6C1 | c.567C>A p.D189E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.248); catalogued as COSV101110420; called by muse, mutect2, varscan2
- OR6C2 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.027); catalogued as rs745352888, COSV100498621; called by muse, mutect2, varscan2
- OR6C74 | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV100667626; called by muse, mutect2, varscan2
- OR6K2 | c.151T>G p.L51V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100656650; called by muse, mutect2, varscan2
- OR6K6 | c.995T>A p.F332Y (on ENST00000368144; = p.F308Y on NM_001005184.1) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100933652; called by muse, mutect2, varscan2
- OR6T1 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189625, COSV58305658; called by muse, mutect2, varscan2
- OR6X1 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100020389; called by muse, mutect2, varscan2
- OR8U1 | c.101T>G p.I34S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1376009317, COSV100163672; called by muse, varscan2
- OR8U1 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs748069339, COSV100163675; called by muse, varscan2
- OSM | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99303976; called by muse, mutect2, varscan2
- OTOP3 | c.429G>T p.W143C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100172494; called by muse, mutect2, varscan2
- P2RX5 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV56593902, COSV99835557; called by muse, mutect2, varscan2
- PACRG | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61309396; called by muse, mutect2, varscan2
- PAK1IP1 | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 48/86 reads (56%) | catalogued as COSV101093282; called by muse, varscan2
- PAK4 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.375); catalogued as rs375220515, COSV100426576; called by muse, mutect2, varscan2
- PANX3 | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99421071, COSV99421739; called by muse, mutect2, varscan2
- PAPPA | c.2112-2A>G p.X704_splice | Splice Site (SNP) | VAF 57/71 reads (80%) | catalogued as COSV100072513; called by muse, mutect2, varscan2
- PARP1 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100828720, COSV64691703; called by muse, mutect2, varscan2
- PARP12 | c.1269G>T p.Q423H | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99693687; called by muse, mutect2, varscan2
- PAX7 | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.322); catalogued as COSV100946484, COSV64753516; called by muse, mutect2
- PBXIP1 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 180/346 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100869962; called by muse, mutect2, varscan2
- PCDH12 | c.1049C>A p.P350Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99185706; called by muse, mutect2, varscan2
- PCDH15 | c.2365G>T p.V789F | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100213033; called by muse, mutect2, varscan2
- PCDH18 | c.2581G>T p.A861S | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100786891; called by muse, mutect2, varscan2
- PCDHA7 | c.1475A>T p.Y492F | Missense Mutation (SNP) | VAF 89/193 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100971168; called by muse, mutect2, varscan2
- PCDHB10 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99503460; called by muse, mutect2, varscan2
- PCDHB11 | c.92G>T p.W31L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV53377581, COSV99503462; called by muse, mutect2, varscan2
- PCDHB11 | c.2179G>T p.V727L | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); catalogued as COSV61314074; called by muse, mutect2, varscan2
- PCDHB12 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53401272, COSV99506512; called by muse, mutect2, varscan2
- PCDHB14 | c.2057T>A p.L686H | Missense Mutation (SNP) | VAF 100/320 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99505400; called by muse, mutect2, varscan2
- PCDHB15 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV99178794; called by muse, mutect2, varscan2
- PCDHB4 | c.1495C>A p.L499I | Missense Mutation (SNP) | VAF 152/518 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV99521730; called by muse, varscan2
- PCDHB5 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.042); catalogued as COSV50674946; called by muse, mutect2, varscan2
- PCDHGA3 | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV54018511, COSV99527969; called by muse, mutect2, varscan2
- PCDHGA9 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99527976; called by muse, mutect2, varscan2
- PCDHGB1 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.029); catalogued as COSV99527973; called by muse, mutect2, varscan2
- PCED1A | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV100642782; called by muse, varscan2
- PCLAF | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100256761, COSV55540047; called by muse, mutect2, varscan2
- PCSK1 | c.1807C>G p.Q603E | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100226721; called by muse, mutect2, varscan2
- PCYOX1 | c.1283C>G p.A428G | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV99713061; called by muse, mutect2, varscan2
- PDE6A | c.1621-1G>T p.X541_splice | Splice Site (SNP) | VAF 28/80 reads (35%) | catalogued as COSV99677544; called by muse, mutect2
- PDILT | c.1381C>G p.P461A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100198914; called by muse, mutect2, varscan2
- PDPN | c.263G>C p.S88T (on ENST00000621990; = p.S164T on NM_006474.4) | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.429); catalogued as COSV99611119, COSV99611796; called by muse, mutect2, varscan2
- PEAR1 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs779577377, COSV52770535; called by muse, mutect2, varscan2
- PEG3 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV99686593; called by muse, mutect2, varscan2
- PHF14 | c.790A>T p.S264C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV101301753; called by muse, mutect2, varscan2
- PHF20 | c.2308G>T p.E770* | Nonsense Mutation (SNP) | VAF 27/130 reads (21%) | catalogued as COSV100926462; called by muse, mutect2, varscan2
- PHLDA3 | c.116A>T p.Q39L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV100943579; called by muse, mutect2, varscan2
- PIGO | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99956319; called by muse, mutect2, varscan2
- PIK3CG | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 81/150 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV63249347, COSV63250489; called by muse, mutect2, varscan2
- PIK3CG | c.2219A>T p.E740V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100782391; called by muse, mutect2, varscan2
- PINK1 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs914435888, COSV100387064; called by muse, mutect2, varscan2
- PITPNB | c.470A>T p.D157V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV100086466; called by muse, mutect2, varscan2
- PKHD1L1 | c.10244G>A p.R3415K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs753944567, COSV101005027, COSV65758606; called by muse, mutect2
- PLXNB2 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100833769; called by muse, mutect2, varscan2
- POLQ | c.7571G>T p.G2524V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99951319; called by mutect2, varscan2
- POLQ | c.4892G>T p.W1631L | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as COSV51760845, COSV99951324; called by muse, mutect2
- POM121C | c.913G>T p.E305* (on ENST00000607367; = p.E63* on NM_001099415.3) | Nonsense Mutation (SNP) | VAF 77/109 reads (71%) | catalogued as COSV99992340; called by muse, mutect2, varscan2
- POP1 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855567; called by muse, mutect2, varscan2
- POTEF | c.2446C>A p.R816S | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV62540059, COSV62540134; called by muse, mutect2, varscan2
- POU2F1 | c.747A>T p.P249= (on ENST00000541643 / NM_001365848.1; = p.P272= on NM_002697.4) | Splice Region (SNP) | VAF 16/29 reads (55%) | catalogued as COSV99610271; called by muse, mutect2, varscan2
- PPEF2 | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV99713983; called by muse, mutect2, varscan2
- PPFIA3 | c.3344G>A p.R1115Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV99417379; called by muse, mutect2, varscan2
- PPIB | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 24/38 reads (63%) | catalogued as CM110806, COSV100254343; called by muse, mutect2, varscan2
- PPP1R3F | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.441); catalogued as COSV99278257; called by muse, mutect2, varscan2
- PRAG1 | c.1562A>C p.Q521P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV100421722; called by muse, mutect2, varscan2
- PRAMEF5 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100871117; called by mutect2, varscan2
- PRDM11 | c.1183G>T p.G395W (on ENST00000530656 / NM_001359633.1; = p.G361W on NM_001256695.1) | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99770184; called by muse, mutect2, varscan2
- PRDM9 | c.194-1G>T p.X65_splice | Splice Site (SNP) | VAF 13/36 reads (36%) | catalogued as COSV57014072, COSV99689521; called by muse, mutect2
- PRMT9 | c.1273A>C p.S425R | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.83); catalogued as COSV100481928, COSV59361918; called by muse, mutect2, varscan2
- PRPH2 | c.697C>A p.H233N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100027882; called by muse, mutect2, varscan2
- PRR23B | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.983); catalogued as COSV100271845; called by muse, mutect2, varscan2
- PRSS36 | c.554-1G>C p.X185_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99191211; called by muse, mutect2, varscan2
- PSG1 | c.711G>A p.P237= | Splice Region (SNP) | VAF 76/496 reads (15%) | catalogued as rs4030951, COSV54946847, COSV54957573; called by muse, varscan2
- PSG11 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 590/814 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs371429789; called by muse, mutect2, varscan2
- PSG9 | c.987C>T p.L329= | Splice Region (SNP) | VAF 63/308 reads (20%) | catalogued as COSV99391928; called by muse, mutect2, varscan2
- PTCD3 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99605859; called by muse, mutect2, varscan2
- PTH2R | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99781957; called by muse, mutect2, varscan2
- PTK7 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV100029683; called by muse, mutect2
- PTMS | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV99179870; called by muse, mutect2, varscan2
- PTP4A1 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101037687; called by muse, mutect2, varscan2
- PTPRO | c.251T>G p.F84C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV99839264; called by muse, mutect2, varscan2
- PTPRU | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs757186665, COSV99057695; called by muse, varscan2
- RAB3C | c.122T>A p.V41E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV99276432; called by muse, mutect2, varscan2
- RABGEF1 | c.226C>T p.R76W (on ENST00000439720 / NM_001287061.2; = p.R63W on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99534418; called by muse, mutect2, varscan2
- RANBP2 | c.5951G>T p.G1984V | Missense Mutation (SNP) | VAF 88/291 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99310953; called by muse, mutect2, varscan2
- RAPH1 | c.3443T>A p.V1148E | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99863199; called by muse, mutect2, varscan2
- RBBP8 | c.1448G>C p.G483A | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as rs777249334, COSV100506947; called by muse, mutect2, varscan2
- RBM15 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100873372; called by muse, mutect2, varscan2
- RBM33 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1335443412, COSV100265070; called by muse, mutect2, varscan2
- RCHY1 | c.443G>T p.C148F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100185660; called by muse, mutect2, varscan2
- RDH14 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs762685241, COSV101173273; called by muse, mutect2, varscan2
- RELN | c.7404G>T p.Q2468H | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100631816; called by muse, mutect2, varscan2
- RELN | c.1925C>A p.A642E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV100631817, COSV59009051; called by muse, mutect2, varscan2
- RELN | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100631819; called by muse, mutect2, varscan2
- RFTN2 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV104400204, COSV99695075, COSV99695456; called by muse, mutect2, varscan2
- RFX6 | c.1894del p.E632Sfs*9 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as COSV60583506; called by mutect2, pindel, varscan2
- RGS18 | c.370A>T p.K124* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100817624; called by muse, mutect2, varscan2
- RHO | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); catalogued as rs774425557, COSV56213028, COSV99960436; called by muse, mutect2, varscan2
- RHO | c.759G>T p.M253I | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs756658659, CM112504, COSV99960438; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RIMS2 | c.3876G>T p.M1292I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV99153387; called by muse, mutect2, varscan2
- RLF | c.3469G>C p.E1157Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV101034932; called by muse, mutect2, varscan2
- RNF139 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as COSV100337675, COSV100337907; called by muse, mutect2, varscan2
- RNF41 | c.253A>G p.N85D | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.503); catalogued as COSV100560083; called by muse, mutect2, varscan2
- ROCK1 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV101296199; called by muse, mutect2, varscan2
- RP1L1 | c.3486C>G p.D1162E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as COSV101222819; called by muse, mutect2, varscan2
- RP1L1 | c.2265C>A p.H755Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV101222820; called by muse, mutect2, varscan2
- RPGRIP1 | c.2663G>T p.R888L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV99250181; called by muse, mutect2, varscan2
- RPL11 | c.275A>T p.E92V (on ENST00000374550 / NM_001199802.1; = p.E93V on NM_000975.5) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV100999653; called by muse, mutect2, varscan2
- RRM2 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100459485; called by muse, mutect2, varscan2
- RRP1B | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV100512796; called by muse, mutect2, varscan2
- RRP8 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV99601758; called by muse, mutect2
- RTL3 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.084); catalogued as COSV100329463; called by muse, mutect2, varscan2
- RYR1 | c.2899G>T p.A967S | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.74); catalogued as COSV100614009, COSV62109299; called by muse, mutect2, varscan2
- RYR1 | c.9391T>A p.Y3131N | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100614010; called by muse, mutect2
- RYR1 | c.10240C>T p.R3414C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs148892609; called by muse, mutect2
- RYR2 | c.6772C>A p.R2258S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100767052, COSV63660486, COSV63705121; called by muse, mutect2
- RYR2 | c.7010G>A p.G2337E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1010394, COSV100767054, COSV100770064; called by muse, mutect2, varscan2
- RYR2 | c.8000C>A p.P2667H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63670479; called by muse, mutect2, varscan2
- S100A9 | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100907192; called by muse, mutect2, varscan2
- SAMD1 | c.1232A>T p.E411V | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99513607; called by muse, mutect2, varscan2
- SAMD9L | c.3937T>C p.C1313R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs934115714, COSV59083560; called by muse, mutect2, varscan2
- SAMSN1 | c.922A>T p.I308F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99580430; called by muse, mutect2
- SAP30BP | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99502612; called by muse, mutect2, varscan2
- SBF2 | c.5507A>G p.Q1836R | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99812610; called by muse, mutect2, varscan2
- SCARF2 | c.1013A>C p.H338P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99838980; called by muse, mutect2, varscan2
- SCG3 | c.84C>G p.D28E | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); catalogued as rs766052539, COSV55023277, COSV99590567; called by muse, mutect2, varscan2
- SCN10A | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101479189; called by muse, varscan2
- SCN7A | c.509C>A p.A170E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV101313121, COSV69268691; called by muse, mutect2
- SEC16A | c.3921C>A p.F1307L | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99255584; called by muse, mutect2, varscan2
- SEMA7A | c.1136A>T p.Q379L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV56092422; called by muse, mutect2, varscan2
- SERTAD2 | c.311del p.P104Rfs*93 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | catalogued as COSV57640075; called by mutect2, pindel, varscan2
- SETDB2 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320417; called by muse, varscan2
- SEZ6L | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 97/190 reads (51%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as rs201869380, COSV99960936; called by muse, mutect2, varscan2
- SF3B1 | c.695G>A p.W232* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100133572; called by muse, mutect2, varscan2
- SF3B2 | c.2635C>G p.Q879E | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV100269402; called by muse, mutect2, varscan2
- SFTPA1 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956853; called by muse, mutect2, varscan2
- SFTPA2 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100958678; called by muse, mutect2, varscan2
- SH3TC1 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99794207; called by muse, mutect2, varscan2
- SHC3 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101011838; called by muse, mutect2, varscan2
- SI | c.3596G>T p.G1199V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52299114; called by muse, mutect2
- SI | c.2651C>A p.T884K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs141329406; called by muse, mutect2, varscan2
- SIGLEC12 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT tolerated (1); PolyPhen possibly damaging (0.729); catalogued as COSV99388952; called by muse, mutect2, varscan2
- SKAP1 | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100411193; called by muse, mutect2, varscan2
- SLAMF6 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100924813; called by muse, mutect2, varscan2
- SLC10A1 | c.818C>G p.A273G | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV99384123; called by muse, mutect2, varscan2
- SLC17A3 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV100398993; called by muse, mutect2, varscan2
- SLC17A4 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs145440760, COSV100930517; called by muse, mutect2, varscan2
- SLC1A6 | c.1103G>C p.R368P | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99693271; called by muse, mutect2, varscan2
- SLC25A3 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99498880; called by muse, mutect2, varscan2
- SLC25A31 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV99829119; called by muse, mutect2
- SLC25A36 | c.433C>G p.R145G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100148921; called by muse, mutect2, varscan2
- SLC25A38 | c.197G>T p.R66I | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99827740; called by muse, mutect2, varscan2
- SLC26A5 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100098406, COSV100100223; called by muse, mutect2, varscan2
- SLC30A6 | c.1008G>C p.W336C | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50871829, COSV50872525; called by muse, mutect2, varscan2
- SLC35G1 | c.419G>A p.G140D (on ENST00000427197 / NM_001134658.3; = p.G139D on NM_153226.4) | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101003993; called by muse, mutect2, varscan2
- SLC39A12 | c.1357G>T p.G453* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101069765; called by muse, mutect2, varscan2
- SLC39A12 | c.1577G>T p.S526I (on ENST00000377369 / NM_001145195.2; = p.S489I on NM_152725.3) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV66201363; called by muse, mutect2, varscan2
- SLC39A13 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54081882; called by muse, mutect2, varscan2
- SLC41A3 | c.1252C>A p.Q418K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259247; called by muse, mutect2, varscan2
- SLC4A10 | c.983G>T p.G328V (on ENST00000446997 / NM_001354461.2; = p.G298V on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99761748; called by muse, mutect2, varscan2
- SLCO5A1 | c.2378G>A p.R793K | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.033); catalogued as COSV52656324, COSV99479145; called by muse, mutect2, varscan2
- SLIT2 | c.3736C>G p.L1246V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99879631; called by muse, mutect2, varscan2
- SMARCA1 | c.2836C>T p.P946S | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946268; called by muse, mutect2, varscan2
- SMARCA4 | c.2124-2A>G p.X708_splice | Splice Site (SNP) | VAF 50/69 reads (72%) | catalogued as COSV100757976; called by muse, mutect2, varscan2
- SMG6 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 74/94 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as rs143294643; called by muse, mutect2, varscan2
- SMOC1 | c.1291G>T p.G431* | Nonsense Mutation (SNP) | VAF 54/73 reads (74%) | catalogued as COSV100734194, COSV62759952; called by muse, mutect2, varscan2
- SMUG1 | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99679265; called by muse, mutect2, varscan2
- SNX4 | c.1067A>T p.K356M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV52537640, COSV99304578; called by muse, mutect2, varscan2
- SOD2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100496545; called by muse, mutect2, varscan2
- SORL1 | c.6571G>T p.D2191Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99492502, COSV99493449; called by muse, mutect2, varscan2
- SOX8 | c.316A>G p.M106V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308170409, COSV99559067; called by muse, mutect2, varscan2
- SPAG17 | c.3580G>C p.E1194Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100307410; called by muse, mutect2, varscan2
- SPAG5 | c.3085A>T p.K1029* | Nonsense Mutation (SNP) | VAF 33/54 reads (61%) | catalogued as COSV99881671; called by muse, mutect2, varscan2
- SPAG7 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99236092; called by muse, mutect2, varscan2
- SPATA6 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.987); catalogued as rs762584721, COSV100892987; called by muse, mutect2, varscan2
- SPEF2 | c.4597G>T p.V1533L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); catalogued as COSV100288610; called by muse, mutect2, varscan2
- SPEG | c.5251G>T p.G1751* | Nonsense Mutation (SNP) | VAF 27/112 reads (24%) | catalogued as COSV100402946; called by muse, mutect2, varscan2
- SPEG | c.7090C>G p.R2364G | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100402948; called by muse, mutect2, varscan2
- SPEG | c.7091G>A p.R2364H | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as COSV100402950; called by muse, mutect2, varscan2
- SPIRE1 | c.1261C>T p.L421F (on ENST00000409402 / NM_001128626.2; = p.L407F on NM_020148.3) | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV59162093; called by muse, mutect2, varscan2
- SPTAN1 | c.6130C>G p.L2044V | Missense Mutation (SNP) | VAF 74/103 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.262); catalogued as COSV100823126; called by muse, mutect2, varscan2
- SPTBN1 | c.4396A>T p.K1466* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100441410, COSV61691823; called by muse, mutect2, varscan2
- SPTBN4 | c.7292T>A p.L2431H | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100149631; called by muse, mutect2, varscan2
- SPTBN5 | c.8134G>T p.D2712Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1010862673, COSV100310350; called by muse, mutect2, varscan2
- ST14 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as rs778899161, COSV53833801, COSV99598356; called by muse, mutect2, varscan2
- ST8SIA2 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV51571968, COSV99184339; called by muse, mutect2, varscan2
- STAB2 | c.5870G>A p.R1957Q | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.649); catalogued as rs538346576, COSV66336715; called by muse, mutect2, varscan2
- STARD5 | c.100-2A>G p.X34_splice | Splice Site (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100250690; called by muse, mutect2
- STK11IP | c.2116G>T p.V706L | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV55257995; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3090G>T p.K1030N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.681); catalogued as COSV100561328; called by muse, mutect2
- STON1-GTF2A1L | c.3090+1G>T p.X1030_splice | Splice Site (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100561330; called by muse, mutect2
- STXBP5L | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99871373; called by muse, mutect2, varscan2
- SUN3 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV52051051, COSV99813712; called by muse, mutect2, varscan2
- SV2B | c.1229G>T p.W410L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100370277; called by muse, mutect2, varscan2
- SYMPK | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs762128952, COSV99841259; called by muse, mutect2, varscan2
- SYNPO2L | c.2620A>G p.I874V (on ENST00000394810 / NM_001114133.3; = p.I650V on NM_024875.5) | Missense Mutation (SNP) | VAF 81/133 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs867136696, COSV100866265; called by muse, mutect2, varscan2
- SYP | c.123T>A p.F41L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99602640; called by muse, mutect2, varscan2
- SYT11 | c.431G>T p.S144I | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV100851262; called by muse, mutect2, varscan2
- SYT6 | c.535C>A p.L179M (on ENST00000610222 / NM_001366225.1; = p.L94M on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.376); catalogued as COSV65775401; called by muse, mutect2, varscan2
- TAF1 | c.4875G>C p.Q1625H (on ENST00000373790 / NM_138923.4; = p.Q1646H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99334023, COSV99335420; called by muse, mutect2, varscan2
- TAF4 | c.3121A>C p.S1041R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV99433239; called by muse, mutect2, varscan2
- TAF5L | c.1372G>T p.G458W | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51078060; called by muse, mutect2, varscan2
- TAS2R14 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0.02); catalogued as rs755402197, COSV101113792; called by muse, mutect2, varscan2
- TBC1D28 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs372865587, COSV100561038; called by muse, mutect2, varscan2
- TBRG4 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as COSV99345196; called by muse, mutect2, varscan2
- TCERG1L | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as rs746436079, COSV100893663; called by muse, mutect2, varscan2
- TELO2 | c.1359G>T p.A453= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99247906; called by muse, mutect2
- TENM2 | c.1049G>T p.R350L (on ENST00000518659 / NM_001122679.2; = p.R159L on NM_001080428.3) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101317443, COSV69123194; called by muse, mutect2, varscan2
- TENM4 | c.4198G>C p.D1400H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV99569412; called by muse, mutect2, varscan2
- TENT4A | c.2131G>C p.A711P | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV100048472; called by muse, mutect2, varscan2
- TEX15 | c.3079G>A p.G1027S (on ENST00000256246; = p.G1410S on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV99820491; called by muse, mutect2, varscan2
- TGFBR3 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV99282198; called by muse, mutect2, varscan2
- THBS2 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV100827461; called by muse, mutect2, varscan2
- THNSL2 | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100147249; called by muse, mutect2, varscan2
- TIAM1 | c.3053G>A p.S1018N | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs760710567, COSV99731726; called by muse, mutect2, varscan2
- TIAM1 | c.837G>C p.E279D | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99731736; called by muse, mutect2, varscan2
- TIGD5 | c.1304G>T p.R435L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99643227; called by muse, mutect2, varscan2
- TIGIT | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs759155389, COSV101047866; called by muse, mutect2, varscan2
- TINAG | c.763del p.R255Efs*2 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as COSV52505250; called by mutect2, pindel, varscan2
- TMEM132A | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99133536; called by muse, mutect2, varscan2
- TMOD3 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100418983; called by muse, mutect2, varscan2
- TMPRSS15 | c.1772T>C p.L591S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as COSV99516374; called by muse, mutect2, varscan2
- TNK2 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100360813; called by muse, mutect2, varscan2
- TNN | c.3479T>A p.V1160E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99510718; called by muse, mutect2, varscan2
- TNNT2 | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV52664670, COSV99371985; called by muse, mutect2, varscan2
- TNR | c.2421C>G p.N807K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.627); catalogued as COSV54870493, COSV54873284, COSV99686713; called by muse, mutect2, varscan2
- TNR | c.1222A>T p.T408S | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99686715; called by muse, mutect2, varscan2
- TOB1 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99278686; called by muse, mutect2, varscan2
- TOX3 | c.1257G>T p.M419I | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as COSV99566863; called by muse, mutect2, varscan2
- TPO | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV100219296; called by muse, mutect2, varscan2
- TRAPPC9 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 36/72 reads (50%) | catalogued as COSV101226288, COSV66904447; called by muse, mutect2, varscan2
- TRERF1 | c.3358C>A p.Q1120K | Missense Mutation (SNP) | VAF 281/512 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs989874404, COSV61680121; called by muse, mutect2, varscan2
- TRHR | c.950C>A p.P317Q | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100304588, COSV61235018; called by muse, mutect2, varscan2
- TRIM10 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV100939565; called by muse, mutect2, varscan2
- TRIM17 | c.100A>G p.N34D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99694445; called by muse, mutect2, varscan2
- TRIM36 | c.1139A>G p.E380G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV99142217; called by muse, mutect2, varscan2
- TRIM39 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100935574; called by muse, mutect2, varscan2
- TRIO | c.9116C>T p.P3039L | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as rs1450897777, COSV100702365; called by muse, mutect2, varscan2
- TRPC3 | c.440G>T p.G147V (on ENST00000379645 / NM_001366479.2; = p.G74V on NM_003305.2) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311870; called by muse, mutect2, varscan2
- TRPC4 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100155405; called by muse, mutect2, varscan2
- TRPM3 | c.1310A>C p.H437P (on ENST00000357533 / NM_001366142.2; = p.H282P on NM_020952.6) | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); catalogued as COSV100676297; called by muse, mutect2, varscan2
- TRPV4 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.85); catalogued as COSV55679436; called by muse, mutect2, varscan2
- TSG101 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99323608; called by muse, mutect2, varscan2
- TSPYL2 | c.951C>A p.Y317* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV100211952; called by muse, mutect2, varscan2
- TYR | c.121G>C p.G41R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as CM033046, COSV99632614; called by muse, mutect2, varscan2
- UBA2 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.162); catalogued as COSV99875250; called by muse, mutect2, varscan2
- UBASH3A | c.1309C>A p.L437M | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369080; called by muse, mutect2, varscan2
- UBN2 | c.1067A>G p.N356S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99943459; called by muse, mutect2, varscan2
- UBQLN2 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100592593; called by muse, mutect2, varscan2
- UEVLD | c.1258G>C p.D420H (on ENST00000396197 / NM_001040697.4; = p.M378I on NM_018314.6) | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100293007; called by muse, mutect2, varscan2
- UGT2B4 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as COSV100522106; called by muse, mutect2, varscan2
- UGT2B4 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100522107; called by muse, mutect2, varscan2
- UMOD | c.1739C>G p.P580R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207849; called by muse, mutect2, varscan2
- URB2 | c.4469G>T p.R1490L | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV99270446; called by muse, mutect2, varscan2
- USH2A | c.7814C>A p.S2605* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100227350; called by muse, mutect2, varscan2
- USP16 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100537745, COSV57624879; called by muse, mutect2, varscan2
- USP20 | c.445A>T p.N149Y | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100203913; called by muse, mutect2, varscan2
- USP28 | c.2995G>T p.D999Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99134362; called by muse, mutect2, varscan2
- USP29 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV54146902, COSV99517460; called by muse, mutect2, varscan2
- USP35 | c.2032G>C p.E678Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.123); catalogued as COSV101489025; called by muse, mutect2, varscan2
- USP37 | c.2299G>T p.D767Y | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV99294008; called by muse, mutect2, varscan2
- USP37 | c.212G>C p.R71P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); catalogued as COSV51444569, COSV99294011, COSV99294569; called by muse, mutect2, varscan2
- USP51 | c.1411G>T p.G471W | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101540632; called by muse, mutect2, varscan2
- VAMP8 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 70/170 reads (41%) | catalogued as COSV55705850; called by muse, mutect2, varscan2
- VCAM1 | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99658073; called by muse, mutect2, varscan2
- VCAN | c.3793G>T p.D1265Y | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54100203; called by muse, mutect2, varscan2
- VGLL3 | c.865T>A p.S289T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101051842; called by muse, mutect2, varscan2
- VNN2 | c.1294A>T p.S432C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100426672; called by muse, mutect2, varscan2
- VSTM2A | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1027478989, COSV100172806; called by muse, mutect2, varscan2
- VSTM2A | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100172808; called by muse, mutect2, varscan2
- WASF3 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100097799, COSV100098817; called by muse, mutect2, varscan2
- WDR17 | c.1990C>A p.R664S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV99706413; called by muse, mutect2, varscan2
- WDR45 | c.767G>T p.S256I (on ENST00000376372 / NM_001029896.2; = p.S257I on NM_007075.3) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540058; called by muse, mutect2, varscan2
- WDR6 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs753315480, COSV100556078; called by muse, mutect2, varscan2
- WDR88 | c.940G>T p.V314L | Missense Mutation (SNP) | VAF 98/120 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV100866365; called by muse, mutect2, varscan2
- WNT16 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV99742815; called by muse, mutect2, varscan2
- WT1 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV100186524; called by muse, mutect2, varscan2
- WWP1 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV99615367; called by muse, mutect2, varscan2
- XIRP2 | c.5038A>C p.K1680Q (on ENST00000628543; = p.K1855Q on NM_152381.6) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV99736637; called by muse, mutect2, varscan2
- YPEL4 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100254171; called by muse, mutect2, varscan2
- ZBBX | c.1730T>A p.L577* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100282833; called by muse, mutect2, varscan2
- ZBBX | c.1274+1G>T p.X425_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as COSV56787509; called by muse, mutect2, varscan2
- ZBTB16 | c.732G>C p.E244D | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV100250722; called by muse, mutect2, varscan2
- ZC3H13 | c.3194G>T p.S1065I | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99667226; called by muse, mutect2, varscan2
- ZC3H7A | c.1886A>T p.Q629L | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT tolerated (0.6); PolyPhen benign (0.101); catalogued as COSV100865425; called by muse, mutect2, varscan2
- ZFYVE26 | c.6100G>C p.A2034P | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100719922; called by muse, mutect2, varscan2
- ZHX1 | c.483G>C p.E161D | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as COSV99933389; called by muse, mutect2, varscan2
- ZHX1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99933391; called by muse, mutect2, varscan2
- ZMYM2 | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101243418; called by muse, mutect2, varscan2
- ZNF131 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); catalogued as COSV100185031; called by muse, mutect2, varscan2
- ZNF280B | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 145/186 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV100840141; called by muse, mutect2, varscan2
- ZNF280C | c.1085A>T p.Y362F | Missense Mutation (SNP) | VAF 69/84 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100921148; called by muse, mutect2, varscan2
- ZNF41 | c.439C>G p.R147G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100491686; called by muse, mutect2, varscan2
- ZNF420 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 75/84 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs754877252, COSV58493433; called by muse, mutect2, varscan2
- ZNF451 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1255094111, COSV100674493; called by muse, mutect2, varscan2
- ZNF488 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as rs376334169; called by muse, mutect2, varscan2
- ZNF527 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100648672; called by muse, mutect2
- ZNF540 | c.1972A>T p.N658Y | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100329390; called by muse, mutect2, varscan2
- ZNF595 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100227339; called by muse, mutect2, varscan2
- ZNF721 | c.868G>A p.E290K (on ENST00000338977; = p.E302K on NM_133474.4) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV100166842; called by muse, mutect2, varscan2
- ZNF770 | c.1542G>T p.Q514H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100695765; called by muse, mutect2, varscan2
- ZNF780A | c.1532G>C p.R511T | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.446); catalogued as COSV100574912; called by muse, mutect2
- ZNF827 | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV101061027, COSV101061497; called by muse, mutect2, varscan2
- ZPLD1 | c.184G>A p.G62S (on ENST00000466937 / NM_001329788.1; = p.G78S on NM_175056.2) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100082806; called by muse, mutect2, varscan2
- ZSWIM5 | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs1409630236, COSV100655213; called by muse, mutect2, varscan2
- ZZZ3 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV100890170; called by muse, mutect2, varscan2
- ABCA9 | c.4418del p.G1473Afs*4 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.7097A>G p.E2366G | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.233); called by muse, mutect2
- ALPP | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.686); called by muse, mutect2
- C17orf78 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CAMTA1 | c.1602del p.E535Rfs*28 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | called by mutect2, pindel, varscan2
- CATSPER1 | c.1130T>G p.M377R | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2
- CCT8L2 | c.919del p.A307Rfs*8 | Frame Shift Del (DEL) | VAF 66/226 reads (29%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2065G>T p.D689Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYSLTR2 | c.795_796del p.L266Efs*19 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by pindel, varscan2
- DNAH10 | c.5069del p.K1690Rfs*13 (on ENST00000409039; = p.K1629Rfs*13 on NM_207437.3) | Frame Shift Del (DEL) | VAF 56/144 reads (39%) | called by mutect2, pindel, varscan2
- ERCC6 | c.287del p.G96Vfs*52 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- GABRG2 | c.967_969delinsCCA p.C323P (on ENST00000361925 / NM_001375343.1; = p.C283P on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (TNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse*, pindel, varscan2*
- GDF2 | c.902_912del p.E301Gfs*48 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- GPR32 | c.510del p.A171Pfs*7 | Frame Shift Del (DEL) | VAF 57/88 reads (65%) | called by mutect2, pindel, varscan2
- GRIN3A | c.1588del p.E530Rfs*2 | Frame Shift Del (DEL) | VAF 34/58 reads (59%) | called by mutect2, pindel, varscan2
- GUCY1A1 | c.1511_1513del p.T504del | In Frame Del (DEL) | VAF 19/33 reads (58%) | called by mutect2, pindel, varscan2
- IGHA1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGLV3-9 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 162/203 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL2RB | c.688A>T p.R230W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- LMX1A | c.656dup p.P220Afs*118 | Frame Shift Ins (INS) | VAF 44/86 reads (51%) | called by mutect2, pindel, varscan2
- LRIT1 | c.846del p.E284Rfs*2 | Frame Shift Del (DEL) | VAF 25/41 reads (61%) | called by mutect2, pindel, varscan2
- NLRP9 | c.1164_1165del p.N388Kfs*34 | Frame Shift Del (DEL) | VAF 54/82 reads (66%) | called by mutect2, pindel, varscan2
- NT5M | c.217_225del p.R73_F75del | In Frame Del (DEL) | VAF 12/19 reads (63%) | called by mutect2, varscan2
- OR6K6 | c.383dup p.M129Dfs*21 (on ENST00000368144; = p.M105Dfs*21 on NM_001005184.1) | Frame Shift Ins (INS) | VAF 37/71 reads (52%) | called by mutect2, pindel, varscan2
- OSBPL8 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2
- PCDHGB5 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIM2 | c.604del p.V202Cfs*61 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 35/438 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- PRAMEF19 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- RBM42 | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.651); called by muse, mutect2
- RFX6 | c.885del p.W295Cfs*49 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel
- RXRB | c.1551del p.I518Sfs*70 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | called by mutect2, pindel, varscan2
- SCAF1 | c.3540del p.T1181Pfs*28 | Frame Shift Del (DEL) | VAF 36/48 reads (75%) | called by mutect2, varscan2
- SETBP1 | c.1312del p.A438Lfs*6 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, pindel*, varscan2
- TECPR1 | c.159_164del p.Q53_Y55delinsH | In Frame Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- TRAV12-3 | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- TRGC1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- USP18 | c.979del p.V327Wfs*42 | Frame Shift Del (DEL) | VAF 16/24 reads (67%) | called by mutect2, varscan2
- ZNF285 | c.713_714insT p.V239Gfs*6 | Frame Shift Ins (INS) | VAF 48/350 reads (14%) | called by mutect2, pindel, varscan2
- ZNF527 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 6/143 reads (4%) | called by muse, mutect2
- AADAT | c.48T>G p.P16= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV100528534; called by muse, mutect2, varscan2
- ABCC6 | c.972C>T p.F324= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99227827; called by muse, mutect2, varscan2
- ABL1 | c.96G>A p.S32= | Silent (SNP) | VAF 28/35 reads (80%) | called by muse, mutect2, varscan2
221 further variants in this file (0 protein-altering or splice-affecting, 203 silent, 18 other) are not listed here.
